Somatic mutation profile of tumor specimen MP2PRT-PAUJND-TMP1-A (aliquot MP2PRT-PAUJND-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUJND, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (395 days).
Specimen MP2PRT-PAUJND-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d4fa39b-a10e-4824-b53c-a002dd3048d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJND-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJND-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb53a129-26eb-4c88-ad59-dcc38bd8d462

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OBSCN | c.23471C>G p.S7824* | Nonsense Mutation (SNP) | VAF 14/252 reads (6%) | catalogued as COSV99066564; called by muse, mutect2
- SMTNL1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 140/383 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs772725041; called by muse, mutect2, varscan2
- IMPG2 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRCH3 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SERPINA6 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2
- SETD2 | c.5274A>G p.I1758M | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SH3BP4 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- SHTN1 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.325); called by muse, mutect2
- THNSL1 | c.1606C>G p.Q536E | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.01); called by muse, mutect2
- TRAF3IP2 | c.1480_1489del p.H494Tfs*5 | Frame Shift Del (DEL) | VAF 69/246 reads (28%) | called by mutect2, pindel*, varscan2*
- TRIM36 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TRPM1 | c.1543A>G p.R515G | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UTRN | c.6683C>T p.P2228L | Missense Mutation (SNP) | VAF 27/333 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.056); called by muse, mutect2
- ITGA10 | c.3249G>A p.T1083= | Silent (SNP) | VAF 30/386 reads (8%) | catalogued as rs145072089; called by muse, mutect2
- LTV1 | c.1173G>A p.K391= | Silent (SNP) | VAF 47/194 reads (24%) | catalogued as COSV52787106; called by muse, mutect2, varscan2
- SGCD | c.258A>G p.Q86= (on ENST00000435422 / NM_001128209.2; = p.Q87= on NM_000337.5) | Silent (SNP) | VAF 60/237 reads (25%) | called by muse, mutect2, varscan2
- SLC39A11 | c.744C>G p.V248= (on ENST00000542342 / NM_001159770.2; = p.V241= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/332 reads (9%) | catalogued as rs146582196; called by muse, mutect2
